Somatic mutation profile of tumor specimen MP2PRT-PAWAKY-TBP1-A (aliquot MP2PRT-PAWAKY-TBP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAWAKY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,041 days).
Specimen MP2PRT-PAWAKY-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17c4cc69-0b50-4265-9b71-297b42437399.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWAKY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWAKY-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d15ba4b-824a-4ff3-bbf6-f547858f5755

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GALNTL5 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 90/291 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267601426, COSV101217812; called by muse, mutect2, varscan2
- SPTB | c.6173C>T p.T2058M | Missense Mutation (SNP) | VAF 129/467 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); catalogued as rs756849461, COSV61552425; called by muse, mutect2, varscan2
- SYNE1 | c.7777C>G p.Q2593E (on ENST00000367255 / NM_182961.4; = p.Q2600E on NM_033071.3) | Missense Mutation (SNP) | VAF 120/372 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772044657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP2A13 | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 103/399 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
